Surgical pathology report (de-identified scan), TCGA case TCGA-AF-A56K, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-A56K-01A (Primary Tumor).

[page 1 of 2]
ICD 0-3
Adenocarcinoma, NOS
8/40/3
Site: Colon, rectosigmoid
C19.9
9/21/12

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Sigmoid and upper rectum
- B. Appendix

CLINICAL NOTES

PRE-OP DIAGNOSIS: Cancerous tumor

GROSS DESCRIPTION

Received are two containers labeled with the patient's name and medical record number.
Container A is additionally labeled "sigmoid and upper rectum." The specimen contains a 25 cm segment of large intestine. Approximately 4 cm from one end of the specimen there is a folded red tumor measuring 6.5 x 5.5 x 5 cm in greatest dimensions. The remainder of the mucosal surface is unremarkable. The tumor is sectioned to show an invasion through the muscular wall and into the surrounding adipose tissue. The proximal and distal margins of resection are grossly free. Lymph node dissection is performed and lymph node candidates are submitted as per block summary.

BLOCK SUMMARY: A1, A2 - proximal and distal margins; A3-A5 - tumor with deepest invasion; A6, A7 - representative sections of tumor; A8 - tumor in normal mucosa; A9 - normal mucosa; A10-A22 - lymph nodes.

B. Container B is labeled with the patient's name, medical record number and "appendix." The appendix demonstrates a single tan tubular structure measuring 9 cm. in length and up to 0.5 cm. in diameter. The serosal surface is tan smooth and glistening. The mucosa is pink and glistening. The thickness of the appendiceal wall is up to 0.3 cm. RS B1, B2

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma
Histologic grade: Moderately-differentiated
Primary tumor (pT): Invades through the muscularis propria and into the pericolic adipose tissue (pT3).
Proximal margin: Uninvolved
Distal margin: Uninvolved
Circumferential (radial) margin: Uninvolved
Vascular invasion: Not identified
Regional lymph nodes (pN): No metastasis is identified in 44 lymph nodes (pN0).
Non-lymph node pericolic tumor: Not identified
Distant metastasis (pM): Cannot be evaluated by the specimen (pMX).
Other findings: The appendix is unremarkable.

[page 2 of 2]
DIAGNOSIS

- A. Sigmoid colon and upper rectum, resection:
- Adenocarcinoma, moderately-differentiated, 6.5 cm. and with invasion through the muscularis propria into the pericolic adipose tissue.
- Surgical margins uninvolved.
- No evidence of metastasis in 44 lymph nodes (0/44).
- B. Appendix, appendectomy:
- No pathologic diagnosis.
-

--- End Of Report ---

Diagnostic Discrepancy		/

Source: NCI Genomic Data Commons file ce912989-3961-46f0-93bd-9e298447d533 (TCGA-AF-A56K.ABD10958-3519-47D7-ABF1-84DB3EA868AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).